Somatic mutation profile of tumor specimen TCGA-BQ-5890-01A (aliquot TCGA-BQ-5890-01A-11D-1589-08) from TCGA case TCGA-BQ-5890, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 69.2 years (25,272 days).
Specimen TCGA-BQ-5890-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92ac9c7c-a385-465d-98c2-de2ebffb0bc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5890-11A (Solid Tissue Normal), aliquot TCGA-BQ-5890-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8316fa6-a70f-4383-943e-f5269cfcfcb4

The open-access MAF lists 84 somatic variants for this specimen: 68 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 15, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.3018C>A p.F1006L | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.071); catalogued as COSV52230529; called by muse, mutect2, varscan2
- ADAM7 | c.1992A>C p.L664F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV51547225; called by muse, mutect2, varscan2
- ADAM7 | c.1993C>A p.H665N | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV51547242; called by muse, mutect2, varscan2
- AGXT | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs180177208, COSV56755984; called by muse, mutect2, varscan2
- ATP13A2 | c.1303C>A p.L435M | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV58704304; called by muse, mutect2, varscan2
- CACNA1S | c.3061T>C p.Y1021H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62944350; called by muse, mutect2, varscan2
- CD81 | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55134288; called by muse, mutect2, varscan2
- CNPPD1 | c.433A>C p.N145H | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55409794; called by muse, mutect2, varscan2
- COG8 | c.1046G>C p.C349S | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV54743710; called by muse, mutect2, varscan2
- CSMD1 | c.3274C>T p.R1092C (on ENST00000520002; = p.R1091C on NM_033225.6) | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480620459, COSV100153077, COSV59278782; called by muse, mutect2, varscan2
- CSPG4 | c.1799G>A p.G600D | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV57892530; called by muse, mutect2, varscan2
- DEF8 | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV51921729; called by muse, mutect2, varscan2
- DNTTIP1 | c.340A>G p.I114V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.114); catalogued as COSV54786589; called by muse, mutect2, varscan2
- ELOVL6 | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV56432679; called by muse, mutect2, varscan2
- ENPP1 | c.2348A>C p.K783T | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV62936883; called by muse, mutect2, varscan2
- ERN1 | c.2734C>T p.R912W | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs185854736, COSV70505067; called by muse, mutect2, varscan2
- FAM13B | c.1652G>C p.R551T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV50375942; called by muse, mutect2, varscan2
- FASN | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60761909; called by muse, mutect2, varscan2
- FCER1G | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV57156312; called by muse, mutect2, varscan2
- FCGR2A | c.887C>A p.P296H (on ENST00000271450 / NM_001136219.3; = p.P295H on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV54841090; called by muse, mutect2, varscan2
- FLRT1 | c.662T>A p.L221H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55368075; called by muse, mutect2, varscan2
- FZD10 | c.920C>A p.T307N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57476200; called by muse, mutect2, varscan2
- INPP4B | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.359); catalogued as COSV53715649, COSV53747965; called by muse, mutect2, varscan2
- KCNC2 | c.1747T>G p.Y583D | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.389); catalogued as COSV54381339; called by muse, mutect2, varscan2
- KCNS1 | c.949T>A p.Y317N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60261229; called by muse, mutect2, varscan2
- KLHL3 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59058450; called by muse, mutect2, varscan2
- KPNB1 | c.1917G>T p.L639F | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV51600992; called by muse, mutect2, varscan2
- LRWD1 | c.1250T>G p.I417S | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52962412; called by muse, mutect2, varscan2
- MAP3K21 | c.2971A>G p.R991G | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV64042827; called by muse, mutect2, varscan2
- MCTP2 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59151229; called by muse, mutect2, varscan2
- MROH2B | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68189213; called by muse, mutect2, varscan2
- MVB12B | c.224G>C p.G75A | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.337); catalogued as COSV63261679; called by muse, mutect2, varscan2
- NAV1 | c.5050G>T p.E1684* | Nonsense Mutation (SNP) | VAF 76/161 reads (47%) | catalogued as COSV55227431; called by muse, mutect2, varscan2
- NELL1 | c.1790T>G p.I597S | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100118505, COSV54292299; called by muse, mutect2, varscan2
- NOC2L | c.689A>C p.D230A | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV58533837; called by muse, mutect2
- NPHP3 | c.2498A>G p.E833G | Missense Mutation (SNP) | VAF 162/292 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV58634009; called by muse, mutect2, varscan2
- NUAK1 | c.1579C>A p.H527N | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV54608848; called by muse, mutect2, varscan2
- PASK | c.2536C>T p.H846Y | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV52161825; called by muse, mutect2, varscan2
- PCDHB9 | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.204); catalogued as COSV53384477; called by muse, mutect2, varscan2
- PEX6 | c.2788G>A p.V930I | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.109); catalogued as COSV55105886; called by muse, mutect2, varscan2
- PLB1 | c.3568A>C p.K1190Q | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV59836837; called by muse, mutect2, varscan2
- PLCB1 | c.2657G>T p.G886V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.676); catalogued as COSV62070934; called by muse, mutect2
- PLEKHA6 | c.257A>T p.D86V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55340966; called by muse, mutect2, varscan2
- PPP1R15A | c.1930G>A p.V644I | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.021); catalogued as COSV52340389; called by muse, mutect2, varscan2
- PRSS21 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV50052377; called by muse, mutect2, varscan2
- PSMA7 | c.344A>C p.K115T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV53383956; called by muse, mutect2, varscan2
- RNF17 | c.427T>C p.L143= | Splice Region (SNP) | VAF 57/184 reads (31%) | catalogued as rs1466690559, COSV55052914; called by muse, mutect2, varscan2
- SETD2 | c.4918-2A>G p.X1640_splice | Splice Site (SNP) | VAF 97/130 reads (75%) | catalogued as COSV57431679; called by muse, mutect2, varscan2
- SLC5A12 | c.266T>A p.L89Q | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.436); catalogued as COSV54825376; called by muse, mutect2, varscan2
- SON | c.4088C>T p.S1363L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs747766069, COSV51671584; called by muse, mutect2, varscan2
- SORBS2 | c.1457A>C p.H486P | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53017438; called by muse, mutect2, varscan2
- SPATA31D1 | c.2688T>G p.S896R | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV61201999; called by muse, mutect2, varscan2
- STX18 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV60376348; called by muse, mutect2, varscan2
- TBCE | c.766A>C p.I256L (on ENST00000366601; = p.I319L on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as COSV64007860; called by muse, mutect2, varscan2
- TFCP2L1 | c.1127G>A p.C376Y | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV55295609; called by muse, mutect2, varscan2
- TIGD4 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs778072168, COSV58550505, COSV58550989; called by muse, mutect2, varscan2
- TNFAIP3 | c.1876C>A p.L626M | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV52802733; called by muse, mutect2, varscan2
- WFDC2 | c.308G>A p.C103Y | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54152103; called by muse, mutect2, varscan2
- YTHDC1 | c.1648A>G p.R550G (on ENST00000344157 / NM_001031732.4; = p.R532G on NM_133370.4) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV60012368; called by muse, mutect2, varscan2
- ZNF418 | c.1550A>G p.K517R | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV68676576; called by muse, mutect2, varscan2
- ZNF502 | c.1011C>G p.N337K | Missense Mutation (SNP) | VAF 72/107 reads (67%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV56075327; called by muse, mutect2, varscan2
- ZNF558 | c.815C>G p.A272G | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV56864562; called by muse, mutect2, varscan2
- ZNF597 | c.175C>G p.P59A | Missense Mutation (SNP) | VAF 85/136 reads (63%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57085776, COSV57085861; called by muse, mutect2
- ZNF773 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as COSV56590696; called by muse, mutect2, varscan2
- ZNF778 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as rs756825808, COSV60603036; called by muse, mutect2, varscan2
- COL14A1 | c.1136dup p.N379Kfs*39 | Frame Shift Ins (INS) | VAF 15/55 reads (27%) | called by mutect2, pindel, varscan2
- HOXA2 | c.1086dup p.T363Yfs*58 | Frame Shift Ins (INS) | VAF 23/163 reads (14%) | called by mutect2, pindel, varscan2
- PBRM1 | c.405del p.A136Pfs*38 | Frame Shift Del (DEL) | VAF 51/99 reads (52%) | called by mutect2, pindel, varscan2
- ABCA9 | c.4305C>T p.I1435= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as rs1461820257, COSV60629371, COSV60631784; called by muse, mutect2, varscan2
- ARID5B | c.321A>G p.E107= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV54430894; called by muse, mutect2, varscan2
- DMBT1 | c.2251C>A p.R751= | Silent (SNP) | VAF 131/405 reads (32%) | catalogued as COSV57565379; called by muse, mutect2, varscan2
- GABRA1 | c.171G>A p.L57= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs760892094, COSV50121708; called by muse, mutect2
- KDM6B | c.4269T>G p.A1423= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV54687800; called by muse, mutect2, varscan2
- LRWD1 | c.1251C>A p.I417= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV52962418; called by muse, mutect2, varscan2
- NUP93 | c.232T>C p.L78= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as rs1458011872, COSV57434529; called by muse, mutect2, varscan2
- PITPNM1 | c.1491C>T p.S497= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV62710118; called by muse, mutect2, varscan2
- PKHD1 | c.5394C>T p.F1798= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV61896814; called by muse, varscan2
- PRPF6 | c.1440G>C p.T480= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV53865866, COSV53879576; called by muse, mutect2, varscan2
- SCUBE3 | c.2517G>A p.K839= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as COSV51460931; called by muse, mutect2, varscan2
- SORBS2 | c.1458C>T p.H486= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as COSV53017417; called by muse, mutect2, varscan2
- SYN2 | c.715C>T p.L239= | Silent (SNP) | VAF 6/9 reads (67%) | catalogued as COSV55140147; called by muse, mutect2, varscan2
- TXN | c.72A>G p.V24= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs1012933057, COSV65731470; called by muse, mutect2, varscan2
- USP31 | c.2430C>A p.T810= | Silent (SNP) | VAF 19/224 reads (8%) | catalogued as COSV54858002; called by muse, mutect2
- AIRE | c.880-100C>T | Intron (SNP) | VAF 55/121 reads (45%) | catalogued as COSV99381410; called by muse, mutect2, varscan2
